National Lung Screening Trial (NLST) participant 210714 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, display field of view 36 cm, reconstruction filter GE Standard.
- T1 (day 353): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, display field of view 38 cm, reconstruction filter GE Standard.
- T2 (day 841): Negative screen, significant abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, display field of view 39 cm, reconstruction filter GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (13 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 93.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Significant cardiovascular abnormality.
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 86; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Emphysema.
- T1 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T1 abnormality 4: Other potentially significant abnormality above the diaphragm; new (not pre-existing on earlier images).
- T1 abnormality 5: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 105; pre-existing on earlier images (earliest visible day 353); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Significant cardiovascular abnormality; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T2 abnormality 3: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 353); interval change does not warrant further investigation.
- T2 abnormality 4: Non-calcified micronodule(s) (opacity < 4 mm diameter); identified only on comparison with prior images.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,218.
